Somatic mutation profile of tumor specimen TCGA-BR-8361-01A (aliquot TCGA-BR-8361-01A-11D-2340-08) from TCGA case TCGA-BR-8361, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 71.2 years (25,999 days).
Specimen TCGA-BR-8361-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d42f4e1a-8bf6-4abe-a1f3-6960dea6d411.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-8361-10A (Blood Derived Normal), aliquot TCGA-BR-8361-10A-01D-2340-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e5955750-ab1a-4d33-8fc3-1b6b53fba772

The open-access MAF lists 1,874 somatic variants for this specimen: 1,427 protein-altering or splice-affecting, 403 silent, 44 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 961, Silent 403, Frame Shift Del 319, Frame Shift Ins 61, Nonsense Mutation 41, Intron 16, Splice Site 16, In Frame Del 14, Splice Region 13, RNA 13, 3'UTR 8, 3'Flank 4.

Variants (750 of 1,874; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGPAT2 | c.202C>T p.R68* | Nonsense Mutation (SNP) | VAF 14/47 reads (30%) | catalogued as rs104894093, CM020918, COSV58248040; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ASPM | c.7308dup p.V2437Cfs*14 | Frame Shift Ins (INS) | VAF 37/137 reads (27%) | catalogued as rs797045315; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AXIN2 | c.1994del p.G665Afs*24 | Frame Shift Del (DEL) | VAF 15/50 reads (30%) | catalogued as rs267606674; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- BRCA2 | c.7543del p.T2515Hfs*9 | Frame Shift Del (DEL) | VAF 39/160 reads (24%) | catalogued as rs80359657; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- COL4A1 | c.2085dup p.G696Rfs*6 | Frame Shift Ins (INS) | VAF 4/22 reads (18%) | catalogued as rs606231464; ClinVar: pathogenic; called by pindel, varscan2
- FBN1 | c.1879C>T p.R627C | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.446); catalogued as rs727503057, CM940760, COSV57315655; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FLNB | c.1592del p.G531Dfs*42 | Frame Shift Del (DEL) | VAF 16/50 reads (32%) | catalogued as rs746105983; ClinVar: pathogenic; called by mutect2, varscan2
- GCDH | c.1173del p.N392Mfs*9 | Frame Shift Del (DEL) | VAF 25/92 reads (27%) | catalogued as rs754002357; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- KCNK9 | c.706G>A p.G236R | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as rs121908332, CM083533, COSV57283374; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.14710C>T p.R4904* | Nonsense Mutation (SNP) | VAF 41/124 reads (33%) | catalogued as rs398123721, CM105476, COSV56414273; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MKRN3 | c.482del p.P161Rfs*10 | Frame Shift Del (DEL) | VAF 8/35 reads (23%) | catalogued as rs763195944; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MOCS2 | c.65del p.P22Hfs*2 | Frame Shift Del (DEL) | VAF 12/72 reads (17%) | catalogued as rs398122799; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SLCO2A1 | c.830del p.F277Sfs*8 | Frame Shift Del (DEL) | VAF 26/120 reads (22%) | catalogued as rs751192029; ClinVar: pathogenic; called by mutect2, varscan2
- SPART | c.696del p.F232Lfs*2 | Frame Shift Del (DEL) | VAF 27/80 reads (34%) | catalogued as rs770560051; ClinVar: pathogenic; called by mutect2, varscan2
- SPG11 | c.3075dup p.E1026Rfs*4 | Frame Shift Ins (INS) | VAF 17/51 reads (33%) | catalogued as rs312262752; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.527G>A p.C176Y | Missense Mutation (SNP) | VAF 32/51 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A3GALT2 | c.448G>A p.V150M | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.116); catalogued as COSV100378220; called by muse, mutect2, varscan2
- AARS2 | c.961T>C p.Y321H | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV55115659; called by muse, mutect2, varscan2
- AASS | c.1412G>A p.R471H | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs767641851, COSV62789741, COSV62790601; called by muse, varscan2
- ABCA13 | c.11083G>A p.V3695I | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); catalogued as COSV71290491; called by muse, varscan2
- ABCA13 | c.13076C>T p.A4359V | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1264686944, COSV68948121; called by muse, mutect2, varscan2
- ABCA2 | c.6736G>A p.G2246S (on ENST00000614293; = p.G2216S on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55802981; called by muse, mutect2, varscan2
- ABCA2 | c.1970G>A p.R657H (on ENST00000614293; = p.R627H on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1194343034, COSV55803004; called by muse, mutect2, varscan2
- ABCB1 | c.2645A>G p.Q882R | Missense Mutation (SNP) | VAF 43/148 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.201); catalogued as COSV55954726; called by muse, mutect2, varscan2
- ABCC5 | c.3269del p.L1090Cfs*26 | Frame Shift Del (DEL) | VAF 14/24 reads (58%) | catalogued as rs749943218; called by mutect2, varscan2
- ABCC6 | c.1324G>A p.V442I | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs372059636; called by muse, mutect2
- ABHD12B | c.361G>A p.E121K (on ENST00000337334 / NM_001206673.2; = p.E44K on NM_181533.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs368157046, COSV61569773, COSV61570289; called by muse, mutect2, varscan2
- ABI3BP | c.1412C>T p.P471L | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs201577974; called by muse, mutect2, varscan2
- ABI3BP | c.871C>A p.L291I | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52540774; called by muse, mutect2, varscan2
- ABTB1 | c.958G>A p.V320I (on ENST00000232744 / NM_172027.3; = p.V178I on NM_032548.3) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368990352; called by muse, mutect2
- AC008397.2 | c.1918C>T p.R640* | Nonsense Mutation (SNP) | VAF 23/59 reads (39%) | catalogued as rs751972854, COSV53207843; called by muse, mutect2, varscan2
- AC093827.5 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55745403; called by muse, varscan2
- ACAD11 | c.2293G>A p.A765T | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.655); catalogued as rs778814949, COSV53898016; called by muse, mutect2, varscan2
- ACAD9 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV58308366; called by muse, mutect2, varscan2
- ACAD9 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs573257268, COSV58306733; called by muse, mutect2, varscan2
- ACAN | c.2439del p.S814Qfs*131 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | catalogued as COSV100717798; called by mutect2, pindel, varscan2
- ACER2 | c.182A>G p.N61S | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.403); catalogued as rs900983915, COSV61820985; called by muse, mutect2, varscan2
- ACKR2 | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs1478191949, COSV56178455; called by muse, mutect2, varscan2
- ACKR4 | c.850G>A p.A284T | Missense Mutation (SNP) | VAF 57/226 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs139794831; called by muse, mutect2, varscan2
- ACO2 | c.2054C>T p.A685V | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.075); catalogued as COSV53443685; called by muse, mutect2, varscan2
- ACSBG1 | c.1192C>T p.R398* | Nonsense Mutation (SNP) | VAF 61/119 reads (51%) | catalogued as rs1351572594, COSV51907598; called by muse, mutect2, varscan2
- ACTL9 | c.349G>A p.G117S | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV61006293; called by muse, varscan2
- ACTL9 | c.287C>T p.T96M | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.397); catalogued as COSV61006300; called by muse, varscan2
- ACTR5 | c.857G>A p.G286D | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.882); catalogued as COSV54761196; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 54/97 reads (56%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAMTS17 | c.3181A>G p.I1061V | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.426); catalogued as rs1157647161, COSV51484645; called by muse, mutect2, varscan2
- ADAMTS4 | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as rs546291574, COSV63487258; called by muse, mutect2, varscan2
- ADAMTS5 | c.2770C>T p.Q924* | Nonsense Mutation (SNP) | VAF 21/44 reads (48%) | catalogued as COSV53180450; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2846C>T p.A949V | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs769726074, COSV65893668; called by muse, mutect2, varscan2
- ADAT3 | c.931G>A p.A311T | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV60191483; called by muse, mutect2, varscan2
- ADCK5 | c.1445G>A p.R482H | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58233758; called by muse, mutect2, varscan2
- ADCY8 | c.401G>A p.C134Y | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV53913238; called by muse, varscan2
- ADGRE2 | c.1787A>C p.K596T | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.394); catalogued as COSV59694435; called by muse, mutect2, varscan2
- ADGRG4 | c.3581G>A p.G1194D | Missense Mutation (SNP) | VAF 36/162 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.243); catalogued as COSV54959853; called by muse, mutect2, varscan2
- ADK | c.835G>A p.V279M (on ENST00000286621; = p.V262M on NM_001123.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs1263409961, COSV54209889; called by muse, mutect2, varscan2
- ADPRH | c.427C>A p.P143T | Missense Mutation (SNP) | VAF 41/207 reads (20%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.956); catalogued as COSV63695258; called by muse, mutect2, varscan2
- ADRA2B | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 7/8 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs775022538, COSV69787722; called by muse, mutect2, varscan2
- ADRB1 | c.1046T>A p.F349Y | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV65168041; called by muse, mutect2, varscan2
- ADRB2 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.687); catalogued as COSV60005755; called by muse, mutect2, varscan2
- ADRB3 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs1349854361, COSV61462192; called by muse, mutect2, varscan2
- AEBP1 | c.1056G>T p.E352D | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as COSV56258964; called by muse, mutect2, varscan2
- AFF4 | c.1133+1G>A p.X378_splice | Splice Site (SNP) | VAF 4/39 reads (10%) | catalogued as COSV54796183; called by muse, mutect2, varscan2
- AGBL5 | c.1266del p.E424Rfs*44 | Frame Shift Del (DEL) | VAF 58/164 reads (35%) | catalogued as rs747733044, COSV59935415; called by mutect2, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 20/56 reads (36%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- AKAP8L | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs775565960, COSV68473763; called by muse, mutect2, varscan2
- AL136295.1 | c.2254G>A p.G752S | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.32); catalogued as rs191087215, COSV55780567; called by muse, mutect2, varscan2
- ALDH16A1 | c.1581del p.Y528Mfs*99 | Frame Shift Del (DEL) | VAF 18/89 reads (20%) | catalogued as rs764766875; called by mutect2, pindel, varscan2
- ALDH3A1 | c.1334del p.P445Rfs*6 | Frame Shift Del (DEL) | VAF 42/89 reads (47%) | catalogued as rs778623472, COSV56735668; called by mutect2, pindel, varscan2
- ALDH3B2 | c.784G>A p.V262M | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.099); catalogued as rs1185932088, COSV62428678; called by muse, mutect2, varscan2
- ALOX5 | c.2000G>A p.R667Q | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs758477278, COSV65553024; called by muse, mutect2, varscan2
- ALPK1 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.751); catalogued as COSV51586817; called by muse, mutect2, varscan2
- AMBN | c.1322C>T p.A441V | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.078); catalogued as COSV59826821; called by muse, mutect2, varscan2
- AMOT | c.2177G>A p.R726H (on ENST00000371959 / NM_001113490.1; = p.R317H on NM_133265.3) | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs762949054, COSV59065040; called by muse, mutect2, varscan2
- AMOT | c.1498G>A p.E500K (on ENST00000371959 / NM_001113490.1; = p.E91K on NM_133265.3) | Missense Mutation (SNP) | VAF 60/202 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs745879297, COSV59065066, COSV59065704; called by muse, mutect2, varscan2
- AMY2A | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 37/352 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs763068700, COSV70214694; called by mutect2, varscan2
- ANK1 | c.4831C>T p.R1611W | Missense Mutation (SNP) | VAF 95/208 reads (46%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.163); catalogued as rs375228300, COSV99227674; called by muse, mutect2, varscan2
- ANKRD11 | c.3262_3264del p.E1088del | In Frame Del (DEL) | VAF 51/168 reads (30%) | catalogued as rs780245711; called by mutect2, pindel, varscan2
- ANKRD20A2P | c.82C>T p.R28* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as rs1351157610, COSV101111886; called by mutect2, varscan2
- ANKRD28 | c.2162C>T p.T721M | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs758981755, COSV67518762; called by muse, mutect2, varscan2
- ANKRD55 | c.1751A>G p.N584S | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0.003); catalogued as COSV61947731; called by muse, mutect2, varscan2
- ANKZF1 | c.943C>T p.Q315* | Nonsense Mutation (SNP) | VAF 32/109 reads (29%) | catalogued as COSV55477205; called by muse, mutect2, varscan2
- ANO8 | c.3058C>T p.R1020C | Missense Mutation (SNP) | VAF 55/176 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as rs578184119, COSV50183716; called by muse, mutect2, varscan2
- ANO9 | c.488C>T p.T163M | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as rs181550038, COSV60450003; called by muse, mutect2, varscan2
- AP3B2 | c.2412G>T p.K804N | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.698); catalogued as COSV55610888; called by muse, mutect2, varscan2
- APLF | c.1115A>G p.N372S | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV58145863; called by muse, mutect2, varscan2
- AR | c.1165C>A p.L389M | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV65958631; called by muse, mutect2
- ARAP1 | c.1869del p.S624Vfs*107 (on ENST00000393609 / NM_001040118.2; = p.S379Vfs*107 on NM_015242.4) | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | catalogued as rs751080362, COSV100501527; called by mutect2, pindel
- ARFGEF2 | c.3917G>A p.R1306Q | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1039724431, COSV64213186; called by muse, mutect2, varscan2
- ARHGAP31 | c.1150G>A p.G384S | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs747126561, COSV51795044; called by muse, mutect2, varscan2
- ARHGAP31 | c.1486C>A p.L496I | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51795052; called by muse, mutect2, varscan2
- ARHGAP32 | c.5306T>G p.V1769G (on ENST00000310343 / NM_001378025.1; = p.V1420G on NM_014715.4) | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as COSV59850442; called by muse, mutect2, varscan2
- ARHGAP45 | c.1829C>T p.A610V | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1402664563, COSV57433332; called by muse, mutect2, varscan2
- ARHGDIG | c.174G>T p.E58D | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as COSV54732636; called by muse, mutect2, varscan2
- ARHGEF1 | c.925T>C p.S309P | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV61528311; called by muse, mutect2, varscan2
- ARHGEF18 | c.2221G>A p.V741I (on ENST00000359920 / NM_001130955.2; = p.V637I on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as rs746816536, COSV60471016; called by muse, mutect2, varscan2
- ARID1A | c.2296del p.Q766Sfs*67 | Frame Shift Del (DEL) | VAF 29/107 reads (27%) | catalogued as COSV61372766; called by mutect2, pindel, varscan2
- ARID1A | c.6310T>C p.S2104P | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61380883, COSV61385450; called by muse, mutect2, varscan2
- ARID5B | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs191606705, COSV54420670; called by muse, mutect2, varscan2
- ARIH1 | c.1658A>G p.E553G | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.587); catalogued as COSV65912048; called by muse, mutect2, varscan2
- ARMC5 | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1168751278, COSV51657526; called by muse, mutect2, varscan2
- ARMH4 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as rs572339718, COSV50761758; called by muse, varscan2
- ARNTL | c.1466G>A p.R489Q (on ENST00000403290 / NM_001297719.2; = p.R488Q on NM_001178.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.142); catalogued as rs1374892939, COSV62987285; called by muse, mutect2, varscan2
- ASB17 | c.220G>A p.V74M | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52410204; called by muse, mutect2, varscan2
- ASCC2 | c.652G>A p.G218R | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); catalogued as rs373380919, COSV57073014; called by muse, mutect2, varscan2
- ASIC4 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.981); catalogued as rs771952448, COSV61731676; called by mutect2, varscan2
- ASTE1 | c.848del p.K283Rfs*22 | Frame Shift Del (DEL) | VAF 32/136 reads (24%) | catalogued as rs34815684; called by mutect2, pindel, varscan2
- ATAD2 | c.3215G>A p.R1072H | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.983); catalogued as COSV54882664; called by muse, mutect2, varscan2
- ATG2A | c.1607A>G p.Y536C | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV65966311; called by mutect2, varscan2
- ATP11B | c.2650del p.Y884Ifs*30 | Frame Shift Del (DEL) | VAF 18/60 reads (30%) | catalogued as rs759638000; called by mutect2, varscan2
- ATP13A2 | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.7); PolyPhen benign (0.015); catalogued as rs773087322, COSV58701472, COSV58703639; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP2B3 | c.1661T>C p.L554P | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV54851779; called by muse, mutect2, varscan2
- ATP2C1 | c.481G>A p.V161I | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.437); catalogued as COSV60758187; called by muse, mutect2, varscan2
- ATP6V0D1 | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as COSV52098670; called by muse, mutect2, varscan2
- ATP8A1 | c.3433G>A p.V1145I | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.142); catalogued as rs779394605, COSV52534956; called by muse, mutect2, varscan2
- ATP8A2 | c.2504G>A p.G835D | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54960082, COSV99683035; called by muse, mutect2, varscan2
- ATR | c.5440del p.R1814Efs*10 | Frame Shift Del (DEL) | VAF 11/58 reads (19%) | catalogued as rs1268253442; called by mutect2, pindel, varscan2
- ATRX | c.6503A>G p.Q2168R | Missense Mutation (SNP) | VAF 49/138 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV64878680; called by muse, mutect2, varscan2
- AURKC | c.182G>T p.R61L (on ENST00000302804 / NM_001015878.2; = p.R27L on NM_003160.3) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV57139030; called by muse, mutect2, varscan2
- B4GALNT1 | c.956G>A p.R319H | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs745356128, COSV57543363; called by muse, mutect2, varscan2
- BAHD1 | c.751A>G p.K251E | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV69084181; called by muse, mutect2, varscan2
- BAP1 | c.295G>A p.V99M | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56236367; called by muse, mutect2, varscan2
- BBS12 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 41/79 reads (52%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs928199736, COSV58561273; called by muse, mutect2, varscan2
- BCAS3 | c.2032G>A p.A678T (on ENST00000390652 / NM_001353144.2; = p.A663T on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.949); catalogued as rs758020100, COSV66776414; called by muse, mutect2, varscan2
- BCL2 | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as rs755908754, COSV61377001; called by muse, mutect2, varscan2
- BCL9L | c.2744C>T p.S915L | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.484); catalogued as rs746679037, COSV52683734; called by muse, mutect2, varscan2
- BICD1 | c.1316A>G p.E439G | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.9); catalogued as COSV55681723; called by muse, mutect2, varscan2
- BLK | c.1109A>G p.E370G | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV52053336; called by muse, mutect2
- BMI1 | c.649A>T p.R217W | Missense Mutation (SNP) | VAF 58/188 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64959239; called by muse, mutect2, varscan2
- BMS1 | c.3279C>T p.S1093= | Splice Region (SNP) | VAF 20/71 reads (28%) | catalogued as rs752119072, COSV65734349; called by muse, mutect2, varscan2
- BMT2 | c.474-2A>G p.X158_splice | Splice Site (SNP) | VAF 27/87 reads (31%) | catalogued as COSV51777898; called by muse, mutect2, varscan2
- BOC | c.1444C>T p.R482C | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs138233485, COSV56353420; called by muse, mutect2, varscan2
- BOP1 | c.139G>A p.G47S | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs549552930, COSV100266080; called by muse, mutect2, varscan2
- BPNT2 | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.197); catalogued as COSV52907979; called by muse, mutect2, varscan2
- BPTF | c.3259del p.I1087* | Frame Shift Del (DEL) | VAF 13/43 reads (30%) | catalogued as rs757520968; called by mutect2, varscan2
- BRD9 | c.1012G>A p.V338M | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs145491306; called by muse, mutect2, varscan2
- BRD9 | c.872C>T p.T291M | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.413); catalogued as rs748289899, COSV60247246; called by muse, mutect2, varscan2
- BRINP1 | c.1654C>T p.R552C | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV56303973; called by muse, mutect2, varscan2
- BRS3 | c.1162A>G p.T388A | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV65711119; called by muse, mutect2, varscan2
- C12orf66 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as rs759325071, COSV61322402; called by muse, mutect2, varscan2
- C16orf78 | c.648C>T p.C216= | Splice Region (SNP) | VAF 11/26 reads (42%) | catalogued as COSV54556982; called by muse, mutect2, varscan2
- C1QTNF7 | c.721C>T p.P241S | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.998); catalogued as COSV54853696; called by muse, mutect2, varscan2
- C1orf112 | c.756del p.F252Lfs*51 | Frame Shift Del (DEL) | VAF 13/52 reads (25%) | catalogued as rs1558068270; called by mutect2, pindel, varscan2
- C1orf141 | c.391C>T p.L131F | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV63992859; called by muse, mutect2
- C1orf87 | c.1550G>T p.S517I | Missense Mutation (SNP) | VAF 88/271 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64597564; called by muse, mutect2, varscan2
- C2CD3 | c.4864C>T p.R1622C | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs377463328; called by muse, mutect2, varscan2
- C2CD6 | c.1855del p.I619Lfs*19 | Frame Shift Del (DEL) | VAF 40/141 reads (28%) | catalogued as rs752496395; called by mutect2, varscan2
- C2orf42 | c.1007del p.K336Sfs*8 | Frame Shift Del (DEL) | VAF 83/302 reads (27%) | catalogued as COSV100034271; called by mutect2, pindel, varscan2
- C5orf24 | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 56/183 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV57543040; called by muse, mutect2, varscan2
- C7orf50 | c.215A>G p.K72R | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as COSV62475944; called by muse, mutect2, varscan2
- CA10 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780641204, COSV53353383; called by muse, mutect2, varscan2
- CABP5 | c.433dup p.R145Pfs*5 | Frame Shift Ins (INS) | VAF 5/36 reads (14%) | catalogued as rs769959570; called by mutect2, pindel, varscan2
- CACNA1A | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV64201789; called by muse, mutect2, varscan2
- CACNA1I | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1024258859, COSV100361589, COSV60811825; called by muse, mutect2, varscan2
- CACNA2D4 | c.728C>T p.T243M | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755897098, COSV54952789; called by muse, mutect2, varscan2
- CACNG7 | c.524A>G p.Y175C | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1175099435, COSV55815364, COSV55815560; called by muse, mutect2, varscan2
- CACTIN | c.427C>T p.R143W | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs761641138, COSV50269196; called by muse, mutect2, varscan2
- CALCR | c.814A>T p.K272* (on ENST00000649521 / NM_001164737.2; = p.K256* on NM_001742.4) | Nonsense Mutation (SNP) | VAF 26/103 reads (25%) | catalogued as COSV64009267; called by muse, mutect2, varscan2
- CAMSAP1 | c.2179G>A p.D727N | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.024); catalogued as rs985084023, COSV56722294; called by muse, mutect2, varscan2
- CASP5 | c.533del p.N178Ifs*8 | Frame Shift Del (DEL) | VAF 78/224 reads (35%) | catalogued as rs765105588; called by mutect2, varscan2
- CASP7 | c.370A>T p.K124* | Nonsense Mutation (SNP) | VAF 27/106 reads (25%) | catalogued as rs755104278, COSV61881818; called by muse, mutect2, varscan2
- CASZ1 | c.1763G>A p.R588H | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1386331680, COSV59737404; called by muse, mutect2, varscan2
- CBR1 | c.509G>T p.G170V | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV51739327; called by muse, mutect2, varscan2
- CBX2 | c.797G>A p.S266N | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV53969380; called by muse, mutect2, varscan2
- CC2D2A | c.3532A>G p.I1178V | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.65); PolyPhen benign (0.046); catalogued as rs1400243836, COSV67504223; called by muse, mutect2, varscan2
- CCBE1 | c.832C>T p.Q278* | Nonsense Mutation (SNP) | VAF 23/67 reads (34%) | catalogued as COSV67950359; called by muse, mutect2, varscan2
- CCDC144A | c.3536T>C p.V1179A | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT tolerated (0.21); PolyPhen benign (0.039); catalogued as rs1334294445, COSV60699329; called by muse, mutect2, varscan2
- CCDC178 | c.1895A>G p.K632R | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.028); catalogued as COSV55780370; called by muse, mutect2, varscan2
- CCDC178 | c.1279del p.T427Hfs*23 | Frame Shift Del (DEL) | VAF 15/35 reads (43%) | catalogued as rs776882105; called by mutect2, pindel, varscan2
- CCDC178 | c.1151del p.N384Mfs*13 | Frame Shift Del (DEL) | VAF 12/45 reads (27%) | catalogued as rs749875431; called by mutect2, pindel, varscan2
- CCDC30 | c.1898A>C p.Q633P (on ENST00000340612; = p.Q590P on NM_001080850.3) | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59607451; called by muse, mutect2, varscan2
- CCDC7 | c.1113del p.E372Kfs*9 | Frame Shift Del (DEL) | VAF 36/146 reads (25%) | catalogued as COSV53235438; called by mutect2, pindel, varscan2
- CCDC73 | c.1341del p.E448Kfs*5 | Frame Shift Del (DEL) | VAF 8/27 reads (30%) | catalogued as rs747079826; called by mutect2, varscan2
- CCER1 | c.1151del p.L384* | Frame Shift Del (DEL) | VAF 25/84 reads (30%) | catalogued as rs1565866062; called by mutect2, pindel, varscan2
- CCM2L | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as rs868769334, COSV52950078; called by muse, mutect2, varscan2
- CCND2 | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs143681287, COSV54224084; called by muse, mutect2, varscan2
- CCT8L2 | c.1654dup p.I552Nfs*6 | Frame Shift Ins (INS) | VAF 41/110 reads (37%) | catalogued as rs780034402; called by mutect2, varscan2
- CCT8L2 | c.1358C>T p.A453V | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63462909; called by muse, mutect2, varscan2
- CD276 | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs770116040, COSV59204254; called by muse, mutect2, varscan2
- CD86 | c.824G>A p.R275Q (on ENST00000330540 / NM_175862.5; = p.R269Q on NM_006889.4) | Missense Mutation (SNP) | VAF 43/201 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373228315; called by muse, mutect2, varscan2
- CD93 | c.361del p.E121Rfs*79 | Frame Shift Del (DEL) | VAF 5/11 reads (45%) | catalogued as rs762805003; called by mutect2, varscan2
- CD99 | c.508C>T p.R170W | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as rs202021795, COSV66989434; called by muse, mutect2, varscan2
- CDC25B | c.1106G>A p.R369H (on ENST00000245960 / NM_021873.3; = p.R355H on NM_004358.4) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.93); catalogued as rs746480347, COSV55657708; called by muse, mutect2, varscan2
- CDC42EP1 | c.619C>A p.L207I | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as COSV50757009; called by muse, mutect2, varscan2
- CDH11 | c.626C>T p.S209L | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs746370506, COSV51766892; called by muse, mutect2, varscan2
- CDH11 | c.374C>T p.T125M | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs779652408, COSV51765586; called by muse, mutect2, varscan2
- CDH20 | c.1999G>A p.D667N | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV53012293; called by muse, mutect2, varscan2
- CDH24 | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs754117962, COSV52977988; called by muse, mutect2, varscan2
- CDH4 | c.728A>G p.Y243C | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64660319; called by muse, mutect2, varscan2
- CDH5 | c.928A>G p.T310A | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.113); catalogued as COSV58518263; called by muse, mutect2, varscan2
- CDH6 | c.761T>C p.V254A | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); catalogued as COSV54072510; called by muse, mutect2, varscan2
- CDH8 | c.1739A>G p.D580G | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54876571; called by muse, mutect2, varscan2
- CDH9 | c.1979A>G p.N660S | Missense Mutation (SNP) | VAF 55/174 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV50270199, COSV99163202; called by muse, mutect2, varscan2
- CDHR2 | c.2959T>G p.F987V | Missense Mutation (SNP) | VAF 58/192 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV56140809; called by muse, mutect2, varscan2
- CDHR4 | c.52C>A p.L18I | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV58526416; called by muse, mutect2
- CDK5RAP2 | c.3284T>C p.M1095T | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771782132, COSV62575428; called by muse, mutect2, varscan2
- CDO1 | c.443C>T p.T148M | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs536229174, COSV51664479; called by muse, mutect2, varscan2
- CDT1 | c.1544T>C p.I515T | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as COSV56348782; called by muse, mutect2, varscan2
- CELF2 | c.821-2A>G p.X274_splice (on ENST00000416382 / NM_001025077.3; = p.X281_splice on NM_006561.3 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 13/50 reads (26%) | catalogued as COSV59976943; called by muse, mutect2, varscan2
- CELF6 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV54717361; called by muse, mutect2, varscan2
- CELSR2 | c.4613G>A p.R1538Q | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.083); catalogued as rs148197539; called by muse, mutect2, varscan2
- CEMP1 | c.181A>G p.K61E | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.005); catalogued as COSV53551234; called by muse, mutect2, varscan2
- CENPJ | c.1595C>T p.P532L | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs371842504; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CEP131 | c.2855C>T p.S952L (on ENST00000269392 / NM_001319228.2; = p.S949L on NM_014984.4) | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs773523503, COSV53953879; called by muse, mutect2, varscan2
- CEP95 | c.874G>A p.V292I | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs782087429, COSV73608767; called by muse, mutect2, varscan2
- CEP95 | c.1705A>G p.M569V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.216); catalogued as COSV73609421; called by muse, mutect2, varscan2
- CERKL | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs371438602; called by muse, mutect2, varscan2
- CFAP52 | c.647A>G p.D216G | Missense Mutation (SNP) | VAF 77/125 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV55346118; called by muse, mutect2, varscan2
- CFAP65 | c.360C>T p.P120= (on ENST00000341552 / NM_194302.4; = p.P55= on NM_152389.4) | Splice Region (SNP) | VAF 17/61 reads (28%) | catalogued as rs368785817; called by muse, mutect2, varscan2
- CFHR3 | c.724T>C p.Y242H | Missense Mutation (SNP) | VAF 61/97 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV66402534; called by muse, mutect2, varscan2
- CHAF1A | c.1184A>C p.K395T | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as COSV56673223; called by muse, mutect2, varscan2
- CHD6 | c.1497C>A p.F499L | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.773); catalogued as COSV58558807; called by muse, mutect2, varscan2
- CHERP | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.754); catalogued as COSV52225554; called by muse, mutect2, varscan2
- CHGB | c.329A>G p.E110G | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as COSV66760866; called by muse, mutect2
- CHIT1 | c.392G>A p.S131N | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV55147678; called by muse, mutect2, varscan2
- CHRFAM7A | c.653T>C p.V218A | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55397663; called by muse, varscan2
- CHRFAM7A | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs780538301; called by muse, mutect2, varscan2
- CHRNA10 | c.371C>A p.A124E | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.86); PolyPhen benign (0.012); catalogued as rs771933661, COSV51705385; called by muse, mutect2
- CHST10 | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.043); catalogued as rs367887748, COSV51804118; called by muse, mutect2, varscan2
- CKAP2 | c.1817del p.K606Rfs*14 (on ENST00000378037 / NM_001098525.2; = p.K605Rfs*14 on NM_018204.5) | Frame Shift Del (DEL) | VAF 18/54 reads (33%) | catalogued as rs752250702; called by mutect2, varscan2
- CLCA4 | c.1328A>C p.D443A | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT tolerated (0.98); PolyPhen benign (0.028); catalogued as COSV55369143; called by muse, mutect2, varscan2
- CLCN6 | c.1604G>A p.R535H | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs556741884, COSV56741132; called by muse, mutect2, varscan2
- CLCN6 | c.2266C>T p.R756* | Nonsense Mutation (SNP) | VAF 28/63 reads (44%) | catalogued as rs1444187729, COSV56737961; called by muse, mutect2, varscan2
- CLCNKA | c.941G>A p.R314Q | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs371274486, COSV58891325; called by muse, mutect2, varscan2
- CLCNKB | c.1673T>C p.L558P | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65153585; called by muse, mutect2, varscan2
- CLDN9 | c.451del p.L151Wfs*225 | Frame Shift Del (DEL) | VAF 20/78 reads (26%) | catalogued as rs771833909; called by mutect2, pindel, varscan2
- CLEC14A | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV60563095; called by muse, mutect2
- CLEC6A | c.247T>C p.W83R | Missense Mutation (SNP) | VAF 62/136 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65987577; called by muse, mutect2, varscan2
- CLGN | c.1522dup p.T508Nfs*37 | Frame Shift Ins (INS) | VAF 20/50 reads (40%) | catalogued as rs1217577246; called by mutect2, varscan2
- CLIC2 | c.168-1G>A p.X56_splice | Splice Site (SNP) | VAF 25/74 reads (34%) | catalogued as COSV58937215; called by muse, mutect2, varscan2
- CLIP4 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.463); catalogued as COSV60750005; called by muse, mutect2, varscan2
- CLK2 | c.1399C>T p.R467W (on ENST00000368361 / NM_001294339.2; = p.R466W on NM_003993.4) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56946070; called by muse, mutect2, varscan2
- CLN3 | c.476G>A p.W159* (on ENST00000360019 / NM_001286104.2; = p.W183* on NM_000086.2) | Nonsense Mutation (SNP) | VAF 6/23 reads (26%) | catalogued as COSV61106334; called by muse, mutect2, varscan2
- CLSPN | c.548T>A p.I183N | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV52051923; called by mutect2, varscan2
- CLTC | c.4334T>G p.L1445R | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52249108; called by muse, mutect2, varscan2
- CMKLR1 | c.670C>T p.R224C (on ENST00000312143 / NM_001142344.2; = p.R222C on NM_004072.3) | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200653739, COSV100379461; called by muse, mutect2, varscan2
- CMTR1 | c.2083C>T p.R695W | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as rs1186759850, COSV65090712; called by muse, mutect2, varscan2
- CMTR2 | c.1692G>C p.E564D | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV57603737; called by muse, mutect2, varscan2
- CNGA4 | c.1468C>T p.Q490* | Nonsense Mutation (SNP) | VAF 14/61 reads (23%) | catalogued as COSV66006318; called by muse, mutect2, varscan2
- CNNM1 | c.1970C>G p.P657R | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as COSV63202247, COSV63203808; called by muse, mutect2, varscan2
- CNTNAP5 | c.2212G>A p.D738N | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV70470944; called by muse, mutect2, varscan2
- CNTRL | c.1336del p.I446* | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | catalogued as rs747099268; called by mutect2, varscan2
- COIL | c.587del p.K196Rfs*13 | Frame Shift Del (DEL) | VAF 84/123 reads (68%) | catalogued as rs748995811; called by mutect2, varscan2
- COL11A1 | c.4694C>T p.A1565V | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.034); catalogued as COSV62171454, COSV62187433; called by muse, mutect2, varscan2
- COL12A1 | c.2797C>T p.R933C | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs377223474; called by muse, mutect2, varscan2
- COL17A1 | c.2639G>A p.G880D | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as COSV62227591; called by muse, mutect2, varscan2
- COL20A1 | c.762dup p.N255Efs*66 | Frame Shift Ins (INS) | VAF 11/45 reads (24%) | catalogued as rs749207634; called by mutect2, varscan2
- COL25A1 | c.1657-3del | Splice Region (DEL) | VAF 6/14 reads (43%) | catalogued as rs760493024; called by mutect2, varscan2
- COL27A1 | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs759104028, COSV61927712; called by muse, mutect2, varscan2
- COL27A1 | c.1604A>G p.K535R | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1308219550, COSV61927722; called by muse, mutect2, varscan2
- COL5A1 | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs142933609, COSV65667254; called by muse, mutect2, varscan2
- COL6A2 | c.2237C>T p.A746V | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT tolerated (0.58); PolyPhen benign (0.391); catalogued as rs761863452, COSV56008499; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A2 | c.2956A>G p.T986A | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs1228558670, COSV52426666; called by muse, mutect2, varscan2
- COL7A1 | c.7088G>A p.G2363E | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60397193; called by muse, mutect2, varscan2
- COL7A1 | c.650C>T p.T217M | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs748496940, COSV60393340; called by muse, mutect2, varscan2
- CORIN | c.1615C>T p.R539C | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs201223301, CM132387; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CP | c.1592A>G p.D531G | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52831553; called by muse, mutect2, varscan2
- CPED1 | c.503C>A p.S168Y | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.174); catalogued as COSV60005625; called by muse, mutect2, varscan2
- CPLX2 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as rs1047967443, COSV64001047; called by muse, mutect2, varscan2
- CPNE1 | c.976G>A p.V326M (on ENST00000352393; = p.V331M on NM_003915.5) | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs780606701, COSV58292735; called by muse, mutect2, varscan2
- CPNE5 | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.036); catalogued as rs747460819, COSV55197619; called by muse, mutect2, varscan2
- CPNE6 | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); catalogued as rs1020837669, COSV53744857; called by muse, mutect2, varscan2
- CRACDL | c.1131del p.A378Qfs*121 | Frame Shift Del (DEL) | VAF 4/17 reads (24%) | catalogued as rs767494728, COSV67408370; called by mutect2, pindel, varscan2
- CREB3L3 | c.685A>G p.T229A | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.265); catalogued as COSV50218015, COSV50283378; called by muse, mutect2, varscan2
- CRTC1 | c.1713del p.S572Afs*6 | Frame Shift Del (DEL) | VAF 20/58 reads (34%) | catalogued as rs769538822; called by mutect2, varscan2
- CSF2RA | c.605G>T p.G202V | Missense Mutation (SNP) | VAF 49/348 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV62624341, COSV62625225; called by muse, mutect2, varscan2
- CSGALNACT1 | c.155C>T p.T52M | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.046); catalogued as rs374867184; called by muse, mutect2, varscan2
- CSH2 | c.108del p.F36Lfs*64 | Frame Shift Del (DEL) | VAF 25/183 reads (14%) | catalogued as rs753853116; called by mutect2, pindel, varscan2
- CSMD3 | c.10920del p.F3640Lfs*61 (on ENST00000297405 / NM_001363185.1; = p.F3471Lfs*61 on NM_052900.3) | Frame Shift Del (DEL) | VAF 20/70 reads (29%) | catalogued as rs766438669; called by mutect2, varscan2
- CSPG4 | c.2969G>A p.R990H | Missense Mutation (SNP) | VAF 56/113 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as rs777862563, COSV57897206; called by muse, mutect2, varscan2
- CTDP1 | c.1645G>A p.A549T | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.053); catalogued as COSV50005242; called by muse, mutect2, varscan2
- CTNNA1 | c.645G>T p.Q215H | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as COSV57076588; called by muse, mutect2, varscan2
- CTNNA3 | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.157); catalogued as rs1195868563, COSV65583983; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTNND2 | c.2360C>T p.T787M | Missense Mutation (SNP) | VAF 57/225 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.421); catalogued as rs747052926, COSV58900033; called by muse, mutect2, varscan2
- CTNND2 | c.1268T>A p.I423N | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58900041; called by muse, varscan2
- CTSE | c.1147T>C p.F383L (on ENST00000360218; = p.F378L on NM_001910.4) | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63061055; called by muse, mutect2, varscan2
- CTTNBP2 | c.1508A>G p.Q503R | Missense Mutation (SNP) | VAF 11/266 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.25); catalogued as COSV99354723; called by muse, mutect2
- CUL7 | c.3968T>G p.L1323R | Missense Mutation (SNP) | VAF 11/172 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54818822; called by muse, mutect2
- CUX1 | c.3017T>C p.L1006P | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52904172; called by muse, mutect2, varscan2
- CXXC1 | c.1088G>T p.R363M | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV53275247; called by muse, mutect2, varscan2
- CXorf58 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 66/210 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1418453985, COSV64858469; called by muse, mutect2, varscan2
- CYFIP1 | c.3223G>A p.A1075T | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as rs1053483287, COSV57411409; called by muse, mutect2, varscan2
- CYP11B1 | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs4998896; called by muse, mutect2, varscan2
- CYP1A1 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs368650547; called by muse, mutect2, varscan2
- CYP4V2 | c.571del p.Y191Tfs*7 | Frame Shift Del (DEL) | VAF 33/83 reads (40%) | catalogued as rs1467050790; called by mutect2, pindel, varscan2
- DAAM1 | c.2635C>T p.R879* | Nonsense Mutation (SNP) | VAF 12/46 reads (26%) | catalogued as rs148831209; called by muse, mutect2, varscan2
- DACH2 | c.626T>G p.L209R | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV64173392, COSV64179776; called by muse, mutect2, varscan2
- DAGLA | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as COSV57197364; called by muse, mutect2
- DAXX | c.1615G>C p.A539P | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.403); catalogued as COSV56470649; called by muse, mutect2, varscan2
- DBX1 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as rs1000434461, COSV57054047; called by muse, mutect2, varscan2
- DCAF11 | c.1021C>T p.R341W | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs758460322, COSV58109642; called by muse, mutect2, varscan2
- DCAF12L1 | c.1008G>T p.Q336H | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV64422050; called by muse, mutect2, varscan2
- DCAF5 | c.518G>A p.R173Q | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1252661523, COSV58461149; called by muse, mutect2, varscan2
- DCAF8L1 | c.647A>G p.D216G | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); catalogued as COSV71595365; called by muse, mutect2, varscan2
- DCC | c.1876C>T p.P626S | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59111715; called by muse, mutect2, varscan2
- DCD | c.20T>C p.L7P | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs764041088, COSV99514092; called by muse, mutect2, varscan2
- DCDC2 | c.1198C>T p.R400C | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs777259245, COSV65828550; called by muse, mutect2, varscan2
- DCLK3 | c.764A>G p.E255G | Missense Mutation (SNP) | VAF 51/184 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as rs765396258, COSV69363597; called by muse, mutect2, varscan2
- DCN | c.176A>G p.Q59R | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.363); catalogued as rs1390825846, COSV50007721; called by muse, mutect2, varscan2
- DCST1 | c.239T>A p.I80N | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as COSV55052486; called by muse, mutect2, varscan2
- DCX | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 12/169 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.205); catalogued as rs758499194, COSV57571264; called by muse, mutect2
- DDR1 | c.2519G>C p.C840S (on ENST00000324771; = p.C803S on NM_001954.4) | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61322112; called by muse, mutect2, varscan2
- DDR2 | c.2516G>A p.R839H | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63370536; called by muse, mutect2, varscan2
- DDX17 | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.039); catalogued as COSV53253607; called by muse, mutect2, varscan2
- DDX21 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.897); catalogued as COSV62555912; called by muse, mutect2, varscan2
- DDX39B | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as rs757158055; called by muse, mutect2
- DDX54 | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.531); catalogued as rs201119519, COSV100013696; called by muse, mutect2, varscan2
- DENND5A | c.2923C>A p.P975T | Missense Mutation (SNP) | VAF 110/332 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV60234975; called by muse, mutect2, varscan2
- DGKZ | c.1344_1345insC p.K449Qfs*17 (on ENST00000454345 / NM_001105540.2; = p.K261Qfs*17 on NM_003646.4) | Frame Shift Ins (INS) | VAF 9/39 reads (23%) | catalogued as COSV58984107, COSV58987748; called by mutect2, pindel, varscan2
- DHX32 | c.477-2A>G p.X159_splice | Splice Site (SNP) | VAF 13/35 reads (37%) | catalogued as COSV52941213; called by muse, mutect2, varscan2
- DHX8 | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs763284184, COSV52252181; called by muse, mutect2, varscan2
- DIP2C | c.3554G>A p.G1185E | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV55164194; called by muse, varscan2
- DIPK2B | c.1268G>A p.R423H | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1474836507, COSV67641306; called by muse, mutect2, varscan2
- DISC1 | c.1793-2A>G p.X598_splice | Splice Site (SNP) | VAF 20/83 reads (24%) | catalogued as rs1439572692, COSV54410846; called by muse, mutect2, varscan2
- DISP2 | c.3539C>A p.T1180K | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); catalogued as COSV51126671; called by muse, mutect2, varscan2
- DLAT | c.723del p.V242Wfs*5 | Frame Shift Del (DEL) | VAF 7/38 reads (18%) | catalogued as rs782029228, COSV54771743; called by mutect2, varscan2
- DLG3 | c.2255+1G>A p.X752_splice (on ENST00000374360 / NM_021120.4; = p.X447_splice on NM_020730.3) | Splice Site (SNP) | VAF 12/60 reads (20%) | catalogued as COSV52083865; called by muse, mutect2, varscan2
- DLGAP1 | c.724A>G p.T242A | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.999); catalogued as COSV59814143; called by muse, mutect2, varscan2
- DLGAP2 | c.1424C>T p.P475L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.63); catalogued as rs770888838, COSV70100083; called by muse, mutect2
- DMKN | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.561); catalogued as COSV60087232; called by muse, mutect2, varscan2
- DMXL1 | c.4106G>A p.R1369H | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as rs776741081, COSV60705181; called by muse, mutect2, varscan2
- DNAH1 | c.6776G>A p.R2259H | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as rs780533738, COSV70230950; called by muse, mutect2, varscan2
- DNAH12 | c.276del p.G93Dfs*7 | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | catalogued as rs751671358; called by mutect2, varscan2
- DNAH17 | c.3240G>T p.W1080C | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV101103245; called by muse, mutect2, varscan2
- DNAH2 | c.12781G>A p.V4261M | Missense Mutation (SNP) | VAF 99/148 reads (67%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs769092944, COSV66721410; called by muse, mutect2, varscan2
- DNAH7 | c.1037del p.K346Sfs*23 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | catalogued as rs761292636; called by mutect2, varscan2
- DNAJB5 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.586); catalogued as rs767050639, COSV56626325; called by muse, mutect2, varscan2
- DNM1L | c.1992C>T p.D664= (on ENST00000549701 / NM_012062.5; = p.D627= on NM_005690.4) | Splice Region (SNP) | VAF 11/40 reads (28%) | catalogued as COSV56775296; called by muse, mutect2, varscan2
- DNMT3A | c.176del p.P59Rfs*13 | Frame Shift Del (DEL) | VAF 18/36 reads (50%) | catalogued as COSV53040261; called by mutect2, pindel, varscan2
- DOCK10 | c.6106A>G p.M2036V | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.19); catalogued as COSV51418968; called by muse, mutect2, varscan2
- DOCK11 | c.6067A>G p.M2023V | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); catalogued as rs113662446, COSV52241785; called by muse, mutect2, varscan2
- DOCK2 | c.3431G>A p.R1144Q | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs776606366, COSV56957531; called by muse, varscan2
- DOCK2 | c.3465A>G p.S1155= | Splice Region (SNP) | VAF 21/49 reads (43%) | catalogued as rs1197508889, COSV56964019; called by muse, varscan2
- DOP1A | c.7201A>G p.N2401D | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.112); catalogued as COSV52284579; called by muse, mutect2, varscan2
- DPP3 | c.827A>G p.Q276R | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV64757148; called by muse, mutect2, varscan2
- DRAM2 | c.382A>G p.T128A | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.017); catalogued as COSV54415787; called by muse, mutect2, varscan2
- DSCAML1 | c.4597A>G p.K1533E (on ENST00000321322; = p.K1473E on NM_020693.4) | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV58394898; called by muse, mutect2, varscan2
- DST | c.6949T>A p.S2317T | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.017); catalogued as COSV99759354; called by muse, mutect2, varscan2
- DTX2 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as rs753180358, COSV56861862; called by muse, mutect2, varscan2
- DUOX1 | c.2036G>A p.R679H | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1184439638, COSV58483028; called by muse, mutect2, varscan2
- DUSP10 | c.1004A>G p.Q335R | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60458473; called by muse, mutect2, varscan2
- DUSP3 | c.398C>T p.T133M | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1321500053, COSV56825023; called by muse, mutect2
- DVL1 | c.809G>T p.S270I | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59564001; called by muse, mutect2, varscan2
- DYNLRB2 | c.29G>T p.R10M | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58416540; called by muse, mutect2, varscan2
- DYRK1B | c.1747G>A p.A583T | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV59914195, COSV59914274; called by muse, mutect2, varscan2
- DYRK3 | c.1402C>T p.R468C | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs782350176, COSV65606253; called by muse, mutect2
- DYRK4 | c.1063del p.R355Dfs*12 | Frame Shift Del (DEL) | VAF 29/94 reads (31%) | catalogued as rs768937539; called by mutect2, pindel, varscan2
- DZANK1 | c.1005dup p.T336Dfs*36 (on ENST00000262547 / NM_001099407.1; = p.T137Dfs*36 on NM_018152.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 12/39 reads (31%) | catalogued as rs775441744; called by mutect2, pindel, varscan2
- DZIP1L | c.1841del p.P614Rfs*69 | Frame Shift Del (DEL) | VAF 7/31 reads (23%) | catalogued as COSV59524030; called by mutect2, pindel, varscan2
- E4F1 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776744880, COSV57037772; called by muse, mutect2, varscan2
- ECEL1 | c.397G>A p.G133S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as rs1367190030, COSV58812984; called by muse, mutect2, varscan2
- EFCAB13 | c.1024del p.S342Afs*25 | Frame Shift Del (DEL) | VAF 19/83 reads (23%) | catalogued as rs759569556; called by mutect2, pindel, varscan2
- EFEMP2 | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as rs758563195, COSV57260582; called by muse, mutect2, varscan2
- EFEMP2 | c.400T>C p.C134R | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV57260594; called by muse, mutect2, varscan2
- EFNB3 | c.836del p.G279Vfs*15 | Frame Shift Del (DEL) | VAF 19/32 reads (59%) | catalogued as rs1241382696; called by mutect2, pindel, varscan2
- EFS | c.643C>A p.P215T | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV53732941; called by muse, mutect2, varscan2
- EGR3 | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57833430; called by muse, mutect2, varscan2
- EHMT2 | c.2563del p.L855Cfs*36 | Frame Shift Del (DEL) | VAF 13/36 reads (36%) | catalogued as rs1377283633; called by mutect2, pindel, varscan2
- EIF4G1 | c.3314C>A p.P1105H (on ENST00000346169 / NM_198241.3; = p.P910H on NM_004953.5) | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV59991880; called by muse, mutect2, varscan2
- ELAVL2 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as COSV56358243; called by muse, mutect2, varscan2
- ELK3 | c.525dup p.V176Rfs*14 | Frame Shift Ins (INS) | VAF 19/44 reads (43%) | catalogued as rs769175197; called by mutect2, varscan2
- ELOVL4 | c.65C>T p.T22M | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.62); catalogued as rs1275216390, COSV63954148; called by muse, mutect2
- EMC1 | c.2752C>T p.R918* | Nonsense Mutation (SNP) | VAF 21/74 reads (28%) | catalogued as rs139335524, COSV64346022; called by muse, mutect2, varscan2
- EML5 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs566623060, COSV61341607; called by muse, mutect2, varscan2
- EPAS1 | c.1648C>T p.R550W | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs771840848, COSV55387675; called by muse, mutect2, varscan2
- EPHA1 | c.2221A>C p.S741R | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV51972514; called by muse, mutect2, varscan2
- EPX | c.1034G>A p.G345D | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56595548; called by muse, mutect2, varscan2
- ERAP1 | c.1909G>A p.A637T | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.799); catalogued as rs530052485, COSV57089204; called by muse, mutect2
- ERBB4 | c.649T>C p.C217R | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53512948; called by muse, mutect2, varscan2
- ERC2 | c.1751C>T p.A584V | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.11); catalogued as rs201400364, COSV55631219; called by muse, mutect2, varscan2
- ERCC3 | c.1066A>G p.T356A | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1188002375, COSV53427985; called by muse, mutect2, varscan2
- ERCC6L2 | c.971G>A p.G324E | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV56631814; called by muse, mutect2, varscan2
- ERF | c.896del p.G299Efs*12 | Frame Shift Del (DEL) | VAF 16/32 reads (50%) | catalogued as rs780487406; called by mutect2, pindel, varscan2
- ERGIC3 | c.487C>T p.R163W | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs1036973147, COSV54138826; called by muse, mutect2, varscan2
- ERICH3 | c.1229C>T p.P410L | Missense Mutation (SNP) | VAF 43/208 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.024); catalogued as rs368878615; called by muse, mutect2, varscan2
- ESCO2 | c.1280G>A p.R427H | Missense Mutation (SNP) | VAF 36/59 reads (61%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.988); catalogued as rs768258688, COSV59415216; called by muse, mutect2, varscan2
- ESF1 | c.1024C>T p.R342C | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs572143127, COSV52522047; called by muse, mutect2, varscan2
- ESPN | c.2171C>A p.P724Q | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.059); catalogued as COSV64704680; called by muse, mutect2, varscan2
- ETV3L | c.1078C>A p.P360T | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV71901137; called by muse, mutect2, varscan2
- EVC2 | c.2266A>G p.N756D | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.014); catalogued as COSV60396087; called by muse, mutect2, varscan2
- EYS | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs764308269, COSV60986589; called by muse, mutect2, varscan2
- F13A1 | c.1834C>T p.R612C | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs771433623, COSV53561091; called by muse, mutect2, varscan2
- F2RL3 | c.1073G>A p.R358Q | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs749158087, COSV50185796; called by muse, mutect2
- FAAP100 | c.2302G>A p.V768I | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as rs767477547, COSV59886091; called by muse, mutect2, varscan2
- FAAP100 | c.575A>G p.H192R | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV59886104; called by muse, mutect2, varscan2
- FAM118A | c.700T>C p.C234R | Missense Mutation (SNP) | VAF 57/170 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV53417913; called by muse, mutect2, varscan2
- FAM155A | c.248A>G p.Q83R | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as rs1031404966, COSV65568541; called by muse, mutect2, varscan2
- FAM155B | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52936735; called by muse, mutect2, varscan2
- FAM222A | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as rs200880090, COSV62723544; called by muse, mutect2, varscan2
- FAM3A | c.64G>A p.V22M | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs782638937, COSV59194560; called by muse, mutect2, varscan2
- FAM47C | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.454); catalogued as rs189160727, COSV63727674; called by muse, mutect2
- FAM81B | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 50/184 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.103); catalogued as rs770077907, COSV51980423; called by muse, mutect2, varscan2
- FAN1 | c.1825A>G p.T609A | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62951095; called by muse, mutect2, varscan2
- FASN | c.6581C>T p.A2194V | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.058); catalogued as COSV60756798; called by muse, mutect2
- FAT1 | c.12334G>A p.V4112I | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.062); catalogued as rs767305041, COSV71674783; called by muse, mutect2, varscan2
- FAT1 | c.9769C>T p.R3257W | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200112487, COSV71674784; called by muse, varscan2
- FAT2 | c.12683T>C p.F4228S | Missense Mutation (SNP) | VAF 53/181 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1189100914, COSV55822797; called by muse, mutect2, varscan2
- FBN2 | c.6986G>A p.R2329Q | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.013); catalogued as rs370804151, COSV52543595; called by muse, mutect2, varscan2
- FBP2 | c.760C>T p.H254Y | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64694906; called by muse, mutect2, varscan2
- FBXL17 | c.1508T>C p.V503A | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV62855495; called by muse, mutect2, varscan2
- FBXL3 | c.505G>A p.V169I | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.452); catalogued as rs201531118, COSV62918931; called by muse, mutect2, varscan2
- FBXO21 | c.1193G>A p.R398Q | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.968); catalogued as rs896856144, COSV57971825, COSV57973313; called by muse, mutect2, varscan2
- FBXO47 | c.863C>A p.A288D | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV65242060; called by muse, mutect2, varscan2
- FGD5 | c.1979C>T p.T660M | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs375231003; called by muse, mutect2, varscan2
- FGFR4 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs201257476, COSV52801100; called by muse, mutect2, varscan2
- FIBP | c.596_597del p.F199Cfs*5 | Frame Shift Del (DEL) | VAF 47/138 reads (34%) | catalogued as rs1565281237; called by mutect2, pindel, varscan2
- FICD | c.910G>A p.V304M | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.223); catalogued as rs763250722, COSV57207724, COSV57208281; called by muse, mutect2, varscan2
- FIGNL1 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs146011869; called by muse, mutect2, varscan2
- FILIP1L | c.2701C>T p.P901S (on ENST00000354552 / NM_182909.3; = p.P661S on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/355 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV58771046; called by muse, mutect2, varscan2
- FILIP1L | c.1244T>C p.L415P (on ENST00000354552 / NM_182909.3; = p.L175P on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/207 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV58771059; called by muse, mutect2, varscan2
- FITM2 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.181); catalogued as COSV67679064; called by muse, mutect2, varscan2
- FLT1 | c.2099A>T p.K700I | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.345); catalogued as COSV56731883; called by muse, mutect2, varscan2
- FNDC1 | c.1433C>A p.S478Y | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV51940956; called by muse, mutect2, varscan2
- FNDC3B | c.3593T>C p.L1198S | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV61044612; called by muse, mutect2, varscan2
- FNIP1 | c.826T>G p.S276A | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV57197675; called by muse, mutect2, varscan2
- FOCAD | c.2791del p.S931Afs*11 | Frame Shift Del (DEL) | VAF 14/31 reads (45%) | catalogued as rs776730128; called by mutect2, pindel, varscan2
- FOCAD | c.4131del p.G1378Vfs*12 | Frame Shift Del (DEL) | VAF 14/38 reads (37%) | catalogued as rs887086186, COSV58105885; called by mutect2, varscan2
- FOCAD | c.4832G>A p.R1611H | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs750541536, COSV58102064; called by muse, mutect2, varscan2
- FOXI2 | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV59094612; called by muse, mutect2, varscan2
- FOXJ3 | c.1813C>T p.R605C | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs780372538, COSV62363240; called by muse, mutect2, varscan2
- FOXRED1 | c.941G>A p.G314D | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.093); catalogued as rs778903746, COSV55007464; called by muse, mutect2, varscan2
- FREM2 | c.1217G>A p.R406H | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as COSV54835896; called by muse, mutect2, varscan2
- FRMD5 | c.1430del p.G477Efs*3 | Frame Shift Del (DEL) | VAF 34/109 reads (31%) | catalogued as rs1177793152; called by mutect2, pindel, varscan2
- FSHR | c.475A>T p.T159S | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as COSV58626560; called by muse, mutect2, varscan2
- FSTL5 | c.1280C>A p.S427Y | Missense Mutation (SNP) | VAF 57/143 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV60181675, COSV60203884; called by muse, mutect2, varscan2
- FUBP3 | c.1208G>A p.R403Q | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1403389562, COSV60513903; called by muse, mutect2, varscan2
- FXR1 | c.371del p.N124Ifs*14 | Frame Shift Del (DEL) | VAF 17/69 reads (25%) | catalogued as rs756304971; called by mutect2, varscan2
- GABBR1 | c.2812C>A p.L938M | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.969); catalogued as COSV63543176; called by muse, mutect2, varscan2
- GABBR1 | c.1721del p.P574Qfs*32 | Frame Shift Del (DEL) | VAF 17/64 reads (27%) | catalogued as rs777471402; called by mutect2, pindel, varscan2
- GABBR2 | c.520C>T p.R174W | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52301701; called by muse, varscan2
- GABRA4 | c.1112A>C p.K371T | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV51930334; called by muse, mutect2, varscan2
- GAL3ST3 | c.784G>A p.V262M | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as rs1219816338, COSV61749204; called by muse, mutect2
- GALNT17 | c.920del p.P307Qfs*19 | Frame Shift Del (DEL) | VAF 8/57 reads (14%) | catalogued as rs1384224795; called by mutect2, pindel, varscan2
- GALNT18 | c.1772G>A p.C591Y | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57151632; called by muse, mutect2, varscan2
- GAREM1 | c.1153C>T p.R385* | Nonsense Mutation (SNP) | VAF 28/80 reads (35%) | catalogued as rs1473968911, COSV52511602; called by muse, mutect2, varscan2
- GCN1 | c.5323G>A p.V1775M | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56109912; called by muse, mutect2, varscan2
- GCNA | c.815C>T p.S272L | Missense Mutation (SNP) | VAF 70/204 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); catalogued as rs867425231, COSV65467313; called by muse, varscan2
- GDF10 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs781814156; called by muse, mutect2, varscan2
- GGA3 | c.1055G>A p.G352D (on ENST00000537686 / NM_138619.4; = p.G319D on NM_014001.5) | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV55456171, COSV55457374; called by muse, mutect2, varscan2
- GHITM | c.379A>G p.T127A | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1043539018, COSV64538728; called by muse, mutect2, varscan2
- GHR | c.1541G>A p.C514Y | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.091); catalogued as COSV50117255; called by muse, mutect2, varscan2
- GHSR | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.054); catalogued as rs1177771500, COSV53840233; called by muse, mutect2, varscan2
- GIGYF1 | c.1094A>G p.K365R | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as COSV51943562; called by muse, mutect2, varscan2
- GLB1 | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs754790691, COSV56565177; called by muse, mutect2, varscan2
- GLB1L3 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369203437; called by muse, mutect2, varscan2
- GLCE | c.1587del p.K529Nfs*114 | Frame Shift Del (DEL) | VAF 32/122 reads (26%) | catalogued as COSV55944550; called by mutect2, pindel, varscan2
- GLG1 | c.1502G>A p.R501Q | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.828); catalogued as rs759441082, COSV52669348; called by muse, mutect2, varscan2
- GLI3 | c.2116A>T p.S706C | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67890366; called by muse, mutect2, varscan2
- GLS | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as rs773887348, COSV57843243; called by muse, mutect2, varscan2
- GMFB | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV63737893; called by muse, mutect2, varscan2
- GNAT3 | c.100G>A p.V34I | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.023); catalogued as rs375145572, COSV101242419; called by muse, mutect2, varscan2
- GNGT2 | c.130G>T p.A44S | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.018); catalogued as COSV55930094; called by muse, mutect2, varscan2
- GOLGA4 | c.4098del p.V1367Lfs*10 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | catalogued as rs768760517; called by mutect2, varscan2
- GOLGA7B | c.181G>A p.G61R | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.091); catalogued as rs1466835263, COSV100085588, COSV54003911; called by muse, mutect2, varscan2
- GP1BA | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.839); catalogued as rs755192403, COSV56699895; called by muse, mutect2, varscan2
- GPATCH1 | c.1415G>A p.S472N | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as COSV50117943; called by muse, mutect2, varscan2
- GPR101 | c.856G>A p.A286T | Missense Mutation (SNP) | VAF 77/183 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV53239339, COSV53240415; called by muse, mutect2, varscan2
- GPR45 | c.193A>G p.M65V | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV51524680; called by muse, mutect2, varscan2
- GPR45 | c.995G>A p.R332H | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.557); catalogued as rs1352198171, COSV51523131; called by muse, mutect2, varscan2
- GPRC5B | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs373858726; called by muse, mutect2
- GRIA4 | c.881C>T p.P294L | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.95); PolyPhen benign (0.149); catalogued as COSV56883951; called by muse, mutect2, varscan2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 22/102 reads (22%) | catalogued as rs760757380; called by mutect2, varscan2
- GRIK3 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143358361, COSV66141748; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRIN1 | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.667); catalogued as COSV59297252; called by muse, mutect2
- GRIN3A | c.2477C>G p.P826R | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); catalogued as rs980253043, COSV62455426; called by muse, mutect2, varscan2
- GRIN3A | c.1117G>T p.G373W | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62455432; called by muse, mutect2
- GRIP1 | c.2601G>T p.W867C (on ENST00000359742 / NM_001379345.1; = p.W815C on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/168 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as COSV54014232, COSV54029171; called by muse, mutect2, varscan2
- GRK2 | c.607G>T p.G203C | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57952479; called by muse, mutect2, varscan2
- GRM2 | c.1732G>A p.G578S | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1033638729, COSV56585600; called by muse, mutect2, varscan2
- GTF2H4 | c.1182G>A p.W394* | Nonsense Mutation (SNP) | VAF 16/68 reads (24%) | catalogued as COSV52559598; called by muse, mutect2, varscan2
- GTF3C3 | c.1081del p.T361Lfs*26 | Frame Shift Del (DEL) | VAF 16/53 reads (30%) | catalogued as rs750792116; called by mutect2, varscan2
- GUCY2C | c.2270del p.N757Mfs*8 | Frame Shift Del (DEL) | VAF 38/98 reads (39%) | catalogued as COSV53791141; called by mutect2, pindel, varscan2
- GUCY2F | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV54304537; called by muse, mutect2, varscan2
- GYG2 | c.258G>T p.K86N | Missense Mutation (SNP) | VAF 5/110 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as COSV58550614; called by muse, mutect2
- H2AC1 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.731); catalogued as COSV51237632; called by muse, mutect2, varscan2
- H2BC11 | c.262T>G p.S88A | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.101); catalogued as COSV60362298; called by muse, mutect2, varscan2
- HAPLN1 | c.622G>A p.G208S | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868346551, COSV57149252, COSV57152635; called by muse, mutect2, varscan2
- HBP1 | c.880G>C p.V294L | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as COSV104383143, COSV56018233; called by muse, mutect2, varscan2
- HDGF | c.149del p.F50Sfs*105 | Frame Shift Del (DEL) | VAF 10/25 reads (40%) | catalogued as COSV100625709; called by mutect2, varscan2
- HEATR5A | c.4721G>A p.R1574H | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.246); catalogued as rs750371543, COSV66342492; called by muse, mutect2, varscan2
- HEATR6 | c.227G>A p.S76N | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.6); PolyPhen benign (0.069); catalogued as COSV51746604; called by muse, mutect2, varscan2
- HELZ2 | c.6616del p.R2206Vfs*29 (on ENST00000467148 / NM_001037335.2; = p.R1637Vfs*29 on NM_033405.3) | Frame Shift Del (DEL) | VAF 4/8 reads (50%) | catalogued as rs745497383, COSV101427649; called by mutect2, varscan2
- HERC1 | c.10058A>G p.Y3353C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs758546456, COSV71248477; called by muse, mutect2, varscan2
- HERC1 | c.4349C>T p.A1450V | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (1); PolyPhen probably damaging (0.956); catalogued as COSV71248566; called by muse, mutect2, varscan2
- HIP1R | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760702351, COSV53442562; called by muse, mutect2, varscan2
- HK1 | c.1821G>T p.Q607H | Missense Mutation (SNP) | VAF 51/138 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV53860391; called by muse, mutect2, varscan2
- HMCES | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs751603398, COSV67300136; called by muse, mutect2, varscan2
- HMCN1 | c.13697A>G p.K4566R | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54912018; called by muse, mutect2, varscan2
- HMGCR | c.1793G>A p.R598H | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as rs1228694899, COSV55316374; called by muse, mutect2, varscan2
- HNF4G | c.239A>G p.E80G (on ENST00000354370 / NM_001330561.2; = p.E127G on NM_004133.5) | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV62967944; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.7-3del | Splice Region (DEL) | VAF 4/24 reads (17%) | catalogued as rs759915055; called by pindel, varscan2
- HNRNPL | c.1010del p.P337Hfs*58 | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | catalogued as rs767148651; called by mutect2, varscan2
- HNRNPR | c.1352G>A p.R451H | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.375); catalogued as rs773384635, COSV56422528; called by muse, mutect2, varscan2
- HOXC5 | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54537335; called by muse, mutect2, varscan2
- HROB | c.1592T>C p.L531P | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55369983; called by muse, mutect2, varscan2
- HS1BP3 | c.180G>T p.E60D | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.9); catalogued as COSV58313616; called by muse, mutect2, varscan2
- HS3ST1 | c.784C>T p.R262W | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); catalogued as COSV99136980; called by muse, mutect2, varscan2
- HSDL1 | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs776867049, COSV54740808; called by muse, mutect2, varscan2
- HSPA6 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.495); catalogued as COSV100554219; called by muse, mutect2, varscan2
- HSPH1 | c.2408C>T p.P803L | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs920116149, COSV60711466, COSV60712101, COSV60712802; called by muse, mutect2, varscan2
- HSPH1 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV60712109; called by muse, mutect2, varscan2
- HTR1A | c.823C>A p.L275M | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.315); catalogued as COSV60501404; called by muse, mutect2, varscan2
- HTR3A | c.493C>A p.P165T | Missense Mutation (SNP) | VAF 55/238 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV55470205; called by muse, mutect2, varscan2
- HTR3E | c.1141G>A p.G381S (on ENST00000415389 / NM_001256613.1; = p.G396S on NM_182589.2) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.56); catalogued as rs184749007, COSV58947434; called by muse, mutect2, varscan2
- HVCN1 | c.676C>T p.R226W | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as rs772902585, COSV54371866; called by muse, mutect2, varscan2
- HVCN1 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV54372996; called by muse, mutect2, varscan2
- HYAL2 | c.1184G>A p.R395H | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.722); catalogued as rs143678537; called by muse, mutect2, varscan2
- IFNA6 | c.521C>T p.S174F | Missense Mutation (SNP) | VAF 105/342 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as rs200866459, COSV66506192; called by muse, mutect2, varscan2
- IFNA6 | c.118C>A p.L40I | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.339); catalogued as COSV66506535; called by muse, mutect2, varscan2
- IFT172 | c.2509G>A p.A837T | Missense Mutation (SNP) | VAF 47/158 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.778); catalogued as rs752494593, COSV53131580; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGHV2-5 | c.86C>T p.T29M | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.224); catalogued as rs373990435; called by muse, mutect2, varscan2
- IGLV3-16 | c.147del p.K49Nfs*17 | Frame Shift Del (DEL) | VAF 23/83 reads (28%) | catalogued as rs746629447; called by mutect2, varscan2
- IGLV3-25 | c.269C>T p.T90M | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs377042516; called by muse, varscan2
- IGSF10 | c.5699G>A p.G1900E | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56787077; called by muse, mutect2, varscan2
- IL1F10 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.591); catalogued as COSV61750707; called by muse, mutect2
- IL1RAPL2 | c.1238A>G p.Q413R | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.15); catalogued as COSV61164006; called by muse, mutect2, varscan2
- IL9R | c.85T>C p.C29R | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.878); catalogued as COSV54900504; called by muse, mutect2, varscan2
- IMPDH2 | c.691C>T p.R231W | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV58708231; called by muse, mutect2, varscan2
- INPPL1 | c.3179A>T p.D1060V | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.039); catalogued as COSV53356714; called by muse, mutect2, varscan2
- INSM2 | c.1605dup p.S536* | Frame Shift Ins (INS) | VAF 18/50 reads (36%) | catalogued as rs756928018; called by mutect2, varscan2
- INTS2 | c.1573A>T p.I525F | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV52154120; called by muse, mutect2, varscan2
- INTS4 | c.2507G>A p.R836Q | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV59019417; called by muse, mutect2, varscan2
- INTS6L | c.2209G>A p.A737T | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs374535701, COSV66084868; called by muse, varscan2
- IQGAP3 | c.4537C>T p.R1513W | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs772944929, COSV63252576; called by muse, mutect2, varscan2
- IREB2 | c.95G>A p.G32D | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.53); PolyPhen probably damaging (1); catalogued as COSV51924078; called by muse, mutect2, varscan2
- IRS1 | c.1791del p.H598Tfs*38 | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | catalogued as rs761880048; called by mutect2, varscan2
- IRX1 | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV57360363; called by muse, mutect2, varscan2
- ISLR2 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.387); catalogued as COSV62302300; called by muse, mutect2, varscan2
- ITFG1 | c.1754T>C p.I585T | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57750682; called by muse, mutect2, varscan2
- ITIH5 | c.467del p.F156Sfs*2 | Frame Shift Del (DEL) | VAF 15/65 reads (23%) | catalogued as COSV56919213; called by mutect2, pindel, varscan2
- ITPR2 | c.967C>T p.R323* | Nonsense Mutation (SNP) | VAF 23/61 reads (38%) | catalogued as rs1307132601, COSV67271268; called by muse, mutect2, varscan2
- ITPR3 | c.6839C>A p.P2280H | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.938); catalogued as COSV65411261; called by muse, mutect2, varscan2
- ITPRIP | c.1483C>T p.L495F | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV53392031; called by muse, mutect2, varscan2
- JAK3 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs140784576, COSV71686333; called by muse, mutect2, varscan2
- JAKMIP1 | c.2059G>A p.A687T | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as rs201032711; called by muse, mutect2, varscan2
- JCAD | c.3509C>A p.P1170H | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as COSV64760338; called by muse, mutect2, varscan2
- JOSD1 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1241727196, COSV53265859; called by muse, mutect2, varscan2
- JPH4 | c.1429C>T p.R477W | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.973); catalogued as rs764115938, COSV58113506; called by muse, mutect2, varscan2
- KCNA1 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as rs1273625044, COSV66837848; called by muse, mutect2, varscan2
- KCNA3 | c.625C>T p.R209W | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63902009; called by muse, mutect2
- KCNA3 | c.383C>T p.T128M | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63901232; called by muse, mutect2, varscan2
- KCNB1 | c.649C>G p.L217V | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV65569067; called by muse, mutect2, varscan2
- KCNH4 | c.2397del p.R800Gfs*28 | Frame Shift Del (DEL) | VAF 5/19 reads (26%) | catalogued as rs778022334; called by pindel, varscan2
- KCNH7 | c.3538G>T p.G1180* | Nonsense Mutation (SNP) | VAF 18/52 reads (35%) | catalogued as COSV59801190; called by muse, mutect2, varscan2
- KCNH8 | c.776T>C p.V259A | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.53); catalogued as COSV60467999; called by muse, mutect2, varscan2
- KCNK16 | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs763247743, COSV64678002; called by muse, mutect2
- KCNK3 | c.676G>A p.V226I | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.83); PolyPhen benign (0.024); catalogued as COSV100257305, COSV57193111; called by muse, mutect2, varscan2
- KCNMA1 | c.3599G>A p.S1200N (on ENST00000286628 / NM_001161352.2; = p.S1142N on NM_002247.4) | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); catalogued as COSV54258667; called by muse, mutect2
- KDM2B | c.3016del p.R1006Gfs*37 | Frame Shift Del (DEL) | VAF 7/18 reads (39%) | catalogued as rs1555288650, COSV65639291; called by mutect2, pindel, varscan2
- KDM3B | c.3950del p.P1317Rfs*10 | Frame Shift Del (DEL) | VAF 22/90 reads (24%) | catalogued as rs1561792565; called by mutect2, pindel, varscan2
- KDM4B | c.1111C>T p.R371C | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs1376889896, COSV50228361; called by muse, mutect2
- KDM5C | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62891176; called by muse, mutect2, varscan2
- KDM6A | c.2080del p.A694Lfs*21 | Frame Shift Del (DEL) | VAF 11/29 reads (38%) | catalogued as COSV65045427; called by mutect2, pindel, varscan2
- KIAA1210 | c.3373C>T p.Q1125* | Nonsense Mutation (SNP) | VAF 31/144 reads (22%) | catalogued as COSV68177942; called by muse, mutect2, varscan2
- KIAA1210 | c.1745T>A p.V582D | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.097); catalogued as COSV68177949; called by muse, mutect2, varscan2
- KIF15 | c.3975G>C p.E1325D | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.631); catalogued as COSV58162121; called by muse, mutect2, varscan2
- KIF22 | c.1835C>T p.P612L | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV50716109; called by muse, mutect2, varscan2
- KIF26B | c.3803C>T p.A1268V | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV63644532; called by muse, mutect2, varscan2
- KIF27 | c.2597G>A p.R866K | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52829002; called by muse, mutect2, varscan2
- KIF2B | c.449T>C p.L150P | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as COSV52132191; called by muse, mutect2
- KIF2B | c.1915G>A p.A639T | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.061); catalogued as COSV52129345, COSV52130855; called by muse, mutect2, varscan2
- KIF3B | c.2224C>T p.R742W | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs776982402, COSV65228123; called by muse, mutect2, varscan2
- KIFC3 | c.2339G>A p.G780E | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.544); catalogued as COSV65548890; called by muse, mutect2, varscan2
- KIRREL1 | c.1009del p.L337Sfs*14 | Frame Shift Del (DEL) | VAF 38/123 reads (31%) | catalogued as rs754171400, COSV63285253; called by pindel, varscan2
- KLB | c.80G>T p.R27M | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); catalogued as COSV57302612; called by muse, mutect2, varscan2
- KLF10 | c.713C>T p.T238M | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.869); catalogued as rs759489236, COSV53435890; called by muse, mutect2, varscan2
- KLHL34 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as COSV65279677; called by muse, mutect2
- KLHL4 | c.1882C>A p.P628T | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV64143984, COSV64148115; called by muse, mutect2, varscan2
- KLHL6 | c.212T>C p.L71P | Missense Mutation (SNP) | VAF 54/159 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.737); catalogued as COSV58067371; called by muse, mutect2, varscan2
- KMT2C | c.13858C>G p.H4620D | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV51455830; called by muse, mutect2, varscan2
- KMT2C | c.10967C>T p.A3656V | Missense Mutation (SNP) | VAF 54/153 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV51455851; called by muse, mutect2, varscan2
- KMT2D | c.16447G>A p.A5483T | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV56454793, COSV99985415; called by muse, mutect2, varscan2
- KMT5C | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.717); catalogued as rs748471535, COSV55319611; called by muse, mutect2, varscan2
- KNOP1 | c.652del p.I218Sfs*41 | Frame Shift Del (DEL) | VAF 28/82 reads (34%) | catalogued as rs764099275; called by mutect2, varscan2
- KPNB1 | c.2087T>C p.L696P | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99268372; called by muse, mutect2, varscan2
- KRT13 | c.373C>A p.L125M | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55840375, COSV55840430; called by muse, mutect2, varscan2
- KRT15 | c.1037T>C p.L346P | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54180096; called by muse, mutect2, varscan2
- KRT33B | c.1036C>T p.R346W | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.311); catalogued as rs746705973, COSV52441339; called by muse, mutect2, varscan2
- KRT5 | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); catalogued as COSV52861492; called by muse, mutect2, varscan2
- L3HYPDH | c.308T>C p.M103T | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749414871, COSV54200110; called by muse, mutect2, varscan2
- L3MBTL2 | c.2056A>G p.K686E | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1460192892, COSV53433997; called by muse, mutect2, varscan2
- LAIR1 | c.656G>T p.R219M | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as COSV100479840; called by muse, mutect2, varscan2
- LARGE1 | c.1384C>T p.H462Y | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.216); catalogued as COSV61664455; called by muse, mutect2, varscan2
- LAYN | c.1037T>A p.L346Q (on ENST00000375615 / NM_001258390.1; = p.L338Q on NM_178834.5) | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV65104989, COSV65105432; called by muse, mutect2, varscan2
- LCE2A | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as rs1239398079, COSV64226929; called by muse, mutect2, varscan2
- LCK | c.1186G>A p.A396T | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.434); catalogued as COSV60741152; called by muse, varscan2
- LCT | c.2900G>A p.R967Q | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.499); catalogued as rs1328427364, COSV51544752; called by muse, mutect2, varscan2
- LDLRAP1 | c.604del p.S202Pfs*2 | Frame Shift Del (DEL) | VAF 18/56 reads (32%) | catalogued as COSV65473126, COSV65473260; called by mutect2, varscan2
- LEO1 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs767042967, COSV55175071; called by muse, mutect2, varscan2
- LEPROT | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 74/218 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs753278546, COSV60757723; called by muse, varscan2
- LGR6 | c.1192A>G p.S398G (on ENST00000367278 / NM_001017403.1; = p.S346G on NM_021636.3) | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV55159798; called by muse, mutect2, varscan2
- LILRB1 | c.601C>A p.P201T (on ENST00000427581; = p.P165T on NM_006669.6) | Missense Mutation (SNP) | VAF 36/189 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.245); catalogued as COSV61119239, COSV61121623; called by muse, mutect2, varscan2
- LIN9 | c.392G>A p.R131Q (on ENST00000366808 / NM_001270410.2; = p.R76Q on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.208); catalogued as COSV60245188; called by muse, mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 20/72 reads (28%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LNX2 | c.1960G>A p.V654I | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as rs746076926, COSV60336549; called by muse, mutect2
- LRCH2 | c.1663C>T p.R555W | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs782724339, COSV57753305, COSV57758856; called by muse, mutect2, varscan2
- LRFN3 | c.1199dup p.R401Afs*6 | Frame Shift Ins (INS) | VAF 20/70 reads (29%) | catalogued as rs1236645443; called by mutect2, pindel, varscan2
- LRP1 | c.4268G>A p.R1423H | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs777476570, COSV54515929; called by muse, mutect2, varscan2
- LRP1 | c.4901T>C p.V1634A | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV54515933; called by muse, mutect2, varscan2
- LRP1 | c.12575del p.P4192Qfs*150 | Frame Shift Del (DEL) | VAF 14/62 reads (23%) | catalogued as rs757410385; called by mutect2, varscan2
- LRP1B | c.12611A>G p.N4204S | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV101251572, COSV67238657; called by muse, mutect2, varscan2
- LRP1B | c.6710G>A p.G2237D | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as COSV67238662; called by muse, mutect2, varscan2
- LRP1B | c.4653T>A p.S1551R | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV67238669; called by muse, mutect2, varscan2
- LRRC17 | c.1272del p.K424Nfs*12 | Frame Shift Del (DEL) | VAF 26/72 reads (36%) | catalogued as rs745668314; called by mutect2, varscan2
- LRRC18 | c.170T>G p.L57R | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53282034; called by muse, mutect2, varscan2
- LRRC30 | c.239A>G p.H80R | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.91); PolyPhen benign (0.012); catalogued as COSV67301913; called by muse, mutect2, varscan2
- LRRC3B | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs749724681, COSV67521625; called by muse, mutect2, varscan2
- LRRC45 | c.1351A>G p.M451V | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV60711924; called by muse, mutect2, varscan2
- LRRC46 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV51620319; called by muse, mutect2, varscan2
- LRRC55 | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.137); catalogued as COSV101546782; called by mutect2, varscan2
- LRRC8A | c.400C>T p.L134F | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.078); catalogued as COSV52186964; called by muse, mutect2, varscan2
- LRRK2 | c.4324G>A p.A1442T | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs281865048, CM074928, COSV54158103; called by muse, mutect2, varscan2
- LRRN3 | c.427C>T p.Q143* | Nonsense Mutation (SNP) | VAF 23/70 reads (33%) | catalogued as COSV57821191; called by muse, mutect2, varscan2
- LTBP1 | c.1102G>A p.G368S (on ENST00000404816 / NM_206943.4; = p.G42S on NM_000627.4) | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as COSV63181350, COSV63190597; called by muse, mutect2, varscan2
- LUC7L3 | c.1165dup p.S389Kfs*2 | Frame Shift Ins (INS) | VAF 24/106 reads (23%) | catalogued as rs1229438198; called by mutect2, varscan2
- LUZP1 | c.2183T>C p.M728T | Missense Mutation (SNP) | VAF 75/243 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV56502593; called by muse, mutect2, varscan2
- LYSMD4 | c.164G>A p.R55H (on ENST00000409796 / NM_001284417.2; = p.A26T on NM_152449.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs373755258; called by muse, mutect2, varscan2
- LYZ | c.137-2A>G p.X46_splice | Splice Site (SNP) | VAF 18/80 reads (23%) | catalogued as rs1163497683, COSV54260997; called by muse, mutect2, varscan2
- LZTS1 | c.448C>T p.H150Y | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.276); catalogued as COSV56117319; called by muse, mutect2, varscan2
- LZTS3 | c.1972_1974del p.K658del (on ENST00000329152; = p.K612del on NM_001282533.2) | In Frame Del (DEL) | VAF 24/64 reads (38%) | catalogued as rs778969272; called by pindel, varscan2
- MAB21L1 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as COSV59766696; called by muse, mutect2, varscan2
- MACF1 | c.21520G>T p.A7174S (on ENST00000372915; = p.A5219S on NM_012090.5) | Missense Mutation (SNP) | VAF 18/51 reads (35%) | catalogued as COSV57128289; called by muse, mutect2, varscan2
- MACO1 | c.1012G>A p.A338T | Missense Mutation (SNP) | VAF 48/201 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs930025320, COSV65475152; called by muse, mutect2, varscan2
- MAGEB16 | c.296C>T p.S99L | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.029); catalogued as COSV101303348, COSV67874128; called by muse, mutect2
- MAGEC1 | c.3316G>A p.A1106T | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV53575518; called by muse, mutect2, varscan2
- MAGEE2 | c.334T>G p.S112A | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV64897961; called by muse, mutect2, varscan2
- MAGT1 | c.682C>T p.L228F (on ENST00000618282 / NM_001367916.1; = p.L260F on NM_032121.5) | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.075); catalogued as COSV63782182; called by muse, mutect2, varscan2
- MAN2B2 | c.1727C>T p.A576V | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.019); catalogued as rs767916354, COSV53454161; called by muse, mutect2, varscan2
- MANBA | c.971G>A p.R324K | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.872); catalogued as COSV56966804; called by muse, mutect2, varscan2
- MAP1A | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.945); catalogued as rs780868083, COSV55810175; called by muse, mutect2, varscan2
- MAP1LC3A | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as rs1336843917, COSV54162073; called by muse, mutect2, varscan2
- MAP2 | c.4654C>T p.R1552* | Nonsense Mutation (SNP) | VAF 34/148 reads (23%) | catalogued as COSV52296319; called by muse, mutect2, varscan2
- MAP3K10 | c.1669C>T p.R557* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | catalogued as rs1026126084, COSV53423128; called by muse, mutect2, varscan2
- MAP3K11 | c.251G>T p.W84L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58420422; called by mutect2, varscan2
- MAP3K14 | c.2638C>T p.R880W | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1266880598, COSV59303204; called by muse, mutect2, varscan2
- MAP6 | c.1819G>A p.G607S | Missense Mutation (SNP) | VAF 43/216 reads (20%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.005); catalogued as rs753068936, COSV59076356; called by muse, mutect2, varscan2
- MAPK8IP3 | c.3620A>G p.Y1207C | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51601337; called by muse, mutect2, varscan2
- MARS1 | c.1949T>C p.L650P | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56256051; called by muse, mutect2, varscan2
- MATK | c.263G>A p.R88H (on ENST00000310132 / NM_139355.3; = p.R89H on NM_002378.4) | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.863); catalogued as rs759916673, COSV100036268, COSV59555264; called by muse, mutect2, varscan2
- MBD2 | c.1024G>A p.A342T | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.466); catalogued as rs182260595, COSV56502224; called by muse, mutect2, varscan2
- MBD6 | c.2080del p.Q694Sfs*5 | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | catalogued as rs762648935; called by mutect2, varscan2
- MCM7 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 60/282 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.54); catalogued as rs781082655, COSV57995847; called by muse, mutect2, varscan2
- MCMBP | c.1625C>T p.A542V | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.163); catalogued as rs758779529, COSV63508927; called by muse, mutect2, varscan2
- MDGA2 | c.1206del p.G403Dfs*22 (on ENST00000399232 / NM_001113498.2; = p.G105Dfs*22 on NM_182830.4) | Frame Shift Del (DEL) | VAF 11/44 reads (25%) | catalogued as rs1180255648; called by mutect2, pindel, varscan2
- MDN1 | c.13199A>G p.D4400G | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV65523848; called by muse, mutect2, varscan2
- MDN1 | c.5966del p.K1989Rfs*65 | Frame Shift Del (DEL) | VAF 53/165 reads (32%) | catalogued as rs750092100; called by mutect2, varscan2
- MED1 | c.4375del p.Q1459Rfs*13 | Frame Shift Del (DEL) | VAF 20/62 reads (32%) | catalogued as rs1567917163; called by mutect2, pindel, varscan2
- MED12 | c.3223G>A p.A1075T | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV61344051; called by muse, mutect2, varscan2
- MED14 | c.2153G>A p.R718H | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV61357360; called by muse, mutect2, varscan2
- MED26 | c.1004C>T p.A335V | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs200735730, COSV54661319; called by muse, mutect2, varscan2
- MEGF8 | c.497del p.G166Vfs*53 | Frame Shift Del (DEL) | VAF 4/21 reads (19%) | catalogued as rs762115034; called by mutect2, pindel, varscan2
- METTL25 | c.44C>T p.T15M | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV50259778; called by mutect2, varscan2
- METTL8 | c.461del p.N154Ifs*23 | Frame Shift Del (DEL) | VAF 49/175 reads (28%) | catalogued as rs1268086760; called by mutect2, pindel, varscan2
- MEX3D | c.1918C>T p.R640C | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV66312154; called by muse, mutect2
- MGA | c.3744del p.E1249Rfs*42 | Frame Shift Del (DEL) | VAF 12/33 reads (36%) | catalogued as rs1193719928; called by mutect2, varscan2
- MGAT4C | c.1025del p.P342Lfs*8 | Frame Shift Del (DEL) | VAF 25/94 reads (27%) | catalogued as rs772624713; called by mutect2, pindel, varscan2
- MGST1 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as rs764640311, COSV50566339; called by muse, mutect2, varscan2
- MICOS13 | c.220C>G p.P74A | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.289); catalogued as COSV56798869; called by muse, mutect2
- MIPEP | c.313G>A p.V105M | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs771157026, COSV66134694; called by muse, mutect2, varscan2
- MITF | c.951A>C p.R317S (on ENST00000448226 / NM_006722.3; = p.R217S on NM_000248.4) | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV58832860; called by muse, mutect2, varscan2
- MKX | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs749807102, COSV65391536; called by muse, mutect2, varscan2
- MMP3 | c.190dup p.I64Nfs*33 | Frame Shift Ins (INS) | VAF 8/41 reads (20%) | catalogued as rs782038929; called by mutect2, varscan2
- MMRN2 | c.1226T>G p.V409G | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV64400894; called by muse, mutect2, varscan2
- MMS19 | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs373557835; called by muse, mutect2, varscan2
- MORC4 | c.2354A>G p.E785G | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55243662; called by muse, mutect2, varscan2
- MORC4 | c.1del p.M1? | Frame Shift Del (DEL) | VAF 12/22 reads (55%) | catalogued as rs759643903; called by mutect2, varscan2
- MPP4 | c.1300G>A p.G434R | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59632202; called by muse, mutect2
- MRPL27 | c.431T>G p.L144R | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56812774; called by muse, mutect2, varscan2
- MRPL50 | c.471T>A p.S157R | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.124); catalogued as COSV66406203; called by muse, mutect2, varscan2
- MRPL55 | c.305C>T p.S102L | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.041); catalogued as rs765396403, COSV54342678; called by muse, mutect2, varscan2
- MS4A12 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 59/217 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs111546873, COSV50014503; called by muse, mutect2, varscan2
- MSANTD4 | c.499G>A p.V167I | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.039); catalogued as rs764317441, COSV57285227; called by muse, mutect2, varscan2
- MSGN1 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs928234552, COSV55263114; called by muse, mutect2, varscan2
- MST1 | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV56534502; called by muse, mutect2, varscan2
- MTCL1 | c.3025G>A p.A1009T (on ENST00000306329 / NM_001378206.1; = p.A690T on NM_015210.4) | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.051); catalogued as COSV60407630; called by muse, mutect2, varscan2
- MTCL1 | c.3286C>T p.R1096* (on ENST00000306329 / NM_001378206.1; = p.R777* on NM_015210.4) | Nonsense Mutation (SNP) | VAF 14/54 reads (26%) | catalogued as rs759115819, COSV60404965; called by muse, mutect2
- MTF1 | c.1910C>T p.A637V | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs752547034, COSV65989623; called by muse, mutect2, varscan2
- MTG2 | c.482C>T p.T161M | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761149185, COSV63694124; called by muse, mutect2
- MTMR4 | c.1877G>A p.R626H | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749303819, COSV60201325; called by muse, mutect2, varscan2
- MTO1 | c.1300A>G p.N434D (on ENST00000370300 / NM_133645.3; = p.N409D on NM_012123.4) | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1344099573, COSV64774080; called by muse, mutect2, varscan2
- MTOR | c.2870G>A p.R957Q | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.938); catalogued as rs1201340871, COSV63873476; called by muse, mutect2, varscan2
- MTR | c.1406T>C p.V469A | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV63965090; called by muse, mutect2, varscan2
- MTRR | c.1264A>G p.S422G (on ENST00000264668; = p.S395G on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV52944836; called by muse, mutect2, varscan2
- MTUS2 | c.1014G>T p.E338D | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV70917617; called by muse, mutect2, varscan2
- MUC16 | c.43021C>T p.P14341S | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.927); catalogued as rs374686688; called by muse, mutect2, varscan2
- MUC16 | c.41593C>T p.R13865C | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as rs367857280, COSV66690229; called by muse, mutect2, varscan2
- MUC4 | c.13205C>T p.A4402V (on ENST00000463781 / NM_018406.7; = p.A166V on NM_004532.6) | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV57787725; called by muse, mutect2, varscan2
- MUC6 | c.3832G>A p.V1278I | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs776231978, COSV101424438; called by muse, mutect2
- MUC6 | c.3428G>A p.G1143D | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as COSV70143955; called by muse, mutect2, varscan2
- MYEF2 | c.325T>C p.Y109H | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51049253; called by muse, mutect2, varscan2
- MYH10 | c.5198G>A p.R1733H | Missense Mutation (SNP) | VAF 20/25 reads (80%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as rs371976533; called by muse, mutect2, varscan2
- MYH14 | c.5839C>T p.R1947C | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs747594595, COSV51822283; called by muse, mutect2
- MYH2 | c.5327A>T p.K1776M | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55441208; called by muse, mutect2
- MYH6 | c.5347C>T p.R1783C | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758734120, COSV59304640; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH7B | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.947); catalogued as rs757047463, COSV53421614; called by muse, mutect2, varscan2
- MYH7B | c.2639T>A p.L880H | Missense Mutation (SNP) | VAF 49/156 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53421625; called by muse, mutect2, varscan2
- MYO15A | c.1640C>T p.S547L | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.84); catalogued as rs780435999, COSV52759463; called by muse, mutect2, varscan2
- MYO18B | c.4348C>T p.R1450C | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs527443272, COSV59124910; called by muse, mutect2, varscan2
- MYO18B | c.7304G>A p.R2435H | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs764270244, COSV59138155; called by muse, mutect2, varscan2
- MYO18B | c.7582C>G p.P2528A | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59138581; called by muse, mutect2, varscan2
- MYO1E | c.1132G>A p.D378N | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0.023); catalogued as COSV55689770; called by muse, mutect2, varscan2
- MYO9A | c.4403G>A p.C1468Y | Missense Mutation (SNP) | VAF 51/109 reads (47%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV61853216; called by muse, mutect2, varscan2
- NAA35 | c.1280A>C p.H427P | Missense Mutation (SNP) | VAF 59/175 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as COSV64485288; called by muse, mutect2, varscan2
- NADK | c.1334A>G p.E445G | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs770179015; called by mutect2, varscan2
- NAPG | c.323A>G p.N108S | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV59797473; called by muse, mutect2, varscan2
- NAPSA | c.997del p.V333Sfs*58 | Frame Shift Del (DEL) | VAF 12/62 reads (19%) | catalogued as rs568951683; called by mutect2, pindel, varscan2
- NBEAL2 | c.7766C>T p.A2589V | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as rs953245660, COSV52759775; called by muse, mutect2, varscan2
- NCAM2 | c.10C>A p.L4I | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.046); catalogued as COSV53083552; called by muse, mutect2, varscan2
- NCAN | c.3410-2A>G p.X1137_splice | Splice Site (SNP) | VAF 15/57 reads (26%) | catalogued as COSV53053249; called by muse, mutect2, varscan2
- NCAPD3 | c.4271C>T p.T1424M | Missense Mutation (SNP) | VAF 40/189 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV54453833; called by muse, mutect2, varscan2
- NCAPD3 | c.2725del p.Q909Rfs*10 | Frame Shift Del (DEL) | VAF 23/119 reads (19%) | catalogued as rs770284236; called by mutect2, pindel, varscan2
- NCOA2 | c.3536C>T p.T1179M | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.247); catalogued as rs775589850, COSV51220505; called by muse, mutect2, varscan2
- NCOA3 | c.3467G>A p.R1156Q | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs146235035; called by muse, mutect2, varscan2
- NCOR1 | c.5159G>A p.R1720Q | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.921); catalogued as rs759534850, COSV51981109; called by muse, mutect2, varscan2
- NDST4 | c.188T>C p.M63T | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV52124849; called by muse, mutect2, varscan2
- NDUFA13 | c.357del p.L120* | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | catalogued as rs34327219; called by mutect2, pindel, varscan2
- NDUFS3 | c.82T>C p.S28P | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV55455294; called by muse, mutect2, varscan2
- NEB | c.7679G>A p.G2560D | Missense Mutation (SNP) | VAF 86/344 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV51428773; called by muse, mutect2, varscan2
- NECTIN4 | c.268G>A p.V90M | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); catalogued as COSV63513098; called by muse, mutect2, varscan2
- NES | c.1327G>T p.G443* | Nonsense Mutation (SNP) | VAF 13/78 reads (17%) | catalogued as COSV63961513; called by muse, mutect2, varscan2
- NEUROD2 | c.899G>A p.S300N | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as COSV56911315; called by muse, mutect2, varscan2
- NFATC2 | c.1396C>T p.R466W | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756698530, COSV65357603; called by muse, mutect2, varscan2
- NFKBIA | c.300C>G p.D100E | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.173); catalogued as COSV53753008; called by muse, mutect2, varscan2
- NID1 | c.1912G>A p.V638M | Missense Mutation (SNP) | VAF 58/171 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.503); catalogued as rs748178076, COSV51622825; called by muse, mutect2, varscan2
- NID2 | c.390del p.A131Qfs*33 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | catalogued as COSV53497397, COSV53497910; called by mutect2, pindel, varscan2
- NKRF | c.1507G>A p.A503T | Missense Mutation (SNP) | VAF 45/192 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.346); catalogued as COSV58662071; called by muse, mutect2, varscan2
- NKX6-2 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs776578386, COSV63973598; called by muse, mutect2, varscan2
- NLGN4X | c.2089T>C p.Y697H | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52023943; called by muse, mutect2, varscan2
- NLRC4 | c.674G>A p.G225D | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV61593345; called by muse, mutect2, varscan2
- NLRP8 | c.1643G>A p.S548N | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.191); catalogued as COSV52588387; called by muse, mutect2, varscan2
- NOMO1 | c.1927C>T p.R643W | Missense Mutation (SNP) | VAF 40/213 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs781509308; called by muse, mutect2, varscan2
- NOS1 | c.3274C>T p.P1092S | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.673); catalogued as COSV57615228; called by muse, mutect2, varscan2
- NOTCH4 | c.1044del p.G349Afs*49 | Frame Shift Del (DEL) | VAF 16/103 reads (16%) | catalogued as rs753855314, COSV66678383, COSV66681385; called by mutect2, pindel, varscan2
- NOX5 | c.1790C>T p.A597V | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV52984903, COSV52991006; called by muse, mutect2, varscan2
- NPAS4 | c.1723C>T p.P575S | Missense Mutation (SNP) | VAF 38/203 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60651127; called by muse, mutect2, varscan2
- NPY1R | c.376G>A p.V126M | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56715081; called by muse, mutect2, varscan2
- NR1H4 | c.942A>C p.E314D (on ENST00000551379 / NM_001206993.2; = p.E300D on NM_005123.4) | Missense Mutation (SNP) | VAF 70/196 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0.051); catalogued as COSV51853388; called by muse, mutect2, varscan2
- NR2C2 | c.1689del p.F563Lfs*10 (on ENST00000393102; = p.F582Lfs*10 on NM_003298.5) | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | catalogued as rs774343392; called by mutect2, varscan2
- NR2F6 | c.1201G>A p.G401S | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs370347405; called by muse, mutect2, varscan2
- NR3C1 | c.107G>T p.G36V | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs750532455, COSV51544214; called by muse, mutect2, varscan2
- NR4A2 | c.1507T>C p.F503L | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.472); catalogued as COSV59894382; called by muse, mutect2, varscan2
- NRK | c.1009del p.R337Dfs*8 | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | catalogued as rs1336364406; called by mutect2, pindel, varscan2
- NRROS | c.1816del p.A606Pfs*25 | Frame Shift Del (DEL) | VAF 27/108 reads (25%) | catalogued as COSV100145672; called by mutect2, pindel, varscan2
- NRXN3 | c.1936C>T p.Q646* (on ENST00000335750 / NM_001330195.2; = p.Q273* on NM_004796.6) | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | catalogued as COSV59761768; called by muse, mutect2, varscan2
- NSMF | c.737A>G p.K246R (on ENST00000371475 / NM_001130969.3; = p.K244R on NM_015537.4) | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.969); catalogued as COSV53000954; called by muse, mutect2, varscan2
- NUMA1 | c.2771G>A p.R924H | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as rs750257826, COSV61187178; called by muse, mutect2, varscan2
- NUMA1 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as COSV61187188; called by muse, mutect2, varscan2
- NUP133 | c.551T>C p.I184T | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); catalogued as COSV54572682; called by muse, varscan2
- NUP160 | c.2727T>A p.C909* | Nonsense Mutation (SNP) | VAF 27/109 reads (25%) | catalogued as COSV65854814; called by muse, mutect2, varscan2
- NUP210L | c.2072del p.L691Wfs*3 | Frame Shift Del (DEL) | VAF 13/38 reads (34%) | catalogued as rs760869296; called by mutect2, varscan2
- NYNRIN | c.2282C>T p.A761V | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as rs752963794, COSV66843275; called by muse, mutect2, varscan2
1,124 further variants in this file (677 protein-altering or splice-affecting, 403 silent, 44 other) are not listed here.
